Gene-level copy-number profile of tumor specimen C3N-01410-02 from CPTAC case C3N-01410, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,442 days).
Specimen C3N-01410-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0795cc49-1526-4719-a5c9-3b52f9b8636f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01410-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/b6f25c45-024f-4fe9-96b9-4c4d65f7821a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 542; copy number 2: 21,047; copy number 3: 28,097; copy number 4: 5,290; copy number 5: 2,626; copy number 6: 557; copy number 7: 103; copy number 8: 405; copy number 9: 102; copy number 10: 135; copy number 11: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 751 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,093,498–85,646,325, 598 genes, copy number 7–11 (broad region; genes not listed).
- chr11:69,294,151–70,207,390, 26 genes, copy number 7: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr14:32,241,524–39,388,513, 127 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
